Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A2LJ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A2LJ-01A (Primary Tumor).

ICD-0-3
carcinoma, infiltrating lobular, NOS 8520/3
Site: breast, NOS C50.9 lw
8/17/11

Final Diagnosis

Breast, left, total mastectomy: Infiltrating lobular carcinoma, focal solid variant, Nottingham grade II (of III) [tubules 3/3, nuclei 1/3, mitoses 2/3, Nottingham score 6/9], forming a 11.5 x 7.0 x 6.0 cm mass extensively involving the breast [AJCCpT3]. Lobular carcinoma in situ with focal intraluminal necrosis is present. The tumor does not involve the nipple, overlying skin, or underlying chest wall. All surgical resection margins, after re-excision of the deep margin, are negative for tumor (minimum tumor free margin, 0.8 cm, deep margin).

Lymph node, left axillary sentinel, biopsy: One (of 1) axillary sentinel lymph node is positive for metastatic carcinoma with extensive involvement of the subcapsular sinus [AJCCpN1(sn)]. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression. Extranodal extension is not present.

Lymph nodes, left low axillary, dissection: Multiple (17) axillary lymph nodes are negative for metastatic carcinoma.

Seen with Dr.

Source: NCI Genomic Data Commons file 40a9a21d-59c7-47a4-92f1-601541ff6436 (TCGA-AR-A2LJ.5411AC07-09E4-40C3-844F-2DFAA216D947.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).